EXCEPTIONAL_RESPONDERS case ER-B0GH — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5b9fa46b-36c5-4711-b276-6e86ab8aab29

Demographics
Sex at birth: male; Ethnicity: not hispanic or latino; Year of birth: 1951; Vital status: Alive.

Diagnoses (1)
1. Glioblastoma multiforme: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 50.9 years (18,581 days); Year of diagnosis: 2002; AJCC pathologic stage: Stage IV; Prior malignancy: no; Days to last follow up: 5,626 days (15.4 years); Days to best overall response: 436 days (1.2 years); Best overall response: Partial Response.
   Treatment given: Therapeutic agents: Temozolomide; Days to treatment start: 254 days; Days to treatment end: 902 days (2.5 years).

Follow-up (1 entry)
- Days to follow up: 5,626 days (15.4 years); Disease response: Clinical Progression; Progression or recurrence: Yes; Days to progression: 5,626 days (15.4 years); Days progression-free: 5,387 days (14.7 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B0GH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0GH-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 0.
